Somatic mutation profile of tumor specimen TCGA-FS-A4F4-06A (aliquot TCGA-FS-A4F4-06A-12D-A25O-08) from TCGA case TCGA-FS-A4F4, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 69.7 years (25,467 days).
Specimen TCGA-FS-A4F4-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2ecae0cd-285a-47d6-8c77-430e9c8b72e0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FS-A4F4-10B (Blood Derived Normal), aliquot TCGA-FS-A4F4-10B-01D-A25O-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d1a40ea6-cec9-4c75-9085-e26aa3a80ceb

The open-access MAF lists 46 somatic variants for this specimen: 33 protein-altering or splice-affecting, 13 silent.
By variant classification: Missense Mutation 26, Silent 13, Nonsense Mutation 5, Splice Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NF1 | c.1020dup p.V341Cfs*12 | Frame Shift Ins (INS) | VAF 10/32 reads (31%) | catalogued as rs1555610905, CI086448; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ADAM22 | c.2417G>A p.G806E | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV55980326; called by muse, varscan2
- ANK1 | c.1910C>T p.T637M | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs769870526, COSV55878317; called by muse, mutect2, varscan2
- APOL5 | c.67G>C p.G23R | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.198); catalogued as COSV50767208; called by muse, varscan2
- CDKL5 | c.2063A>G p.D688G | Missense Mutation (SNP) | VAF 33/37 reads (89%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV66111816; called by muse, mutect2, varscan2
- CFAP74 | c.4702G>C p.V1568L | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.488); catalogued as COSV60587296; called by muse, mutect2, varscan2
- CNRIP1 | c.212T>G p.L71R | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55148977; called by muse, mutect2, varscan2
- COL4A1 | c.3148G>T p.G1050W | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65427479; called by muse, mutect2, varscan2
- CYP20A1 | c.1063C>T p.R355* | Nonsense Mutation (SNP) | VAF 15/43 reads (35%) | catalogued as rs766534946, COSV61909709; called by muse, mutect2
- ENTPD3 | c.1479C>A p.F493L | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV57194791; called by muse, mutect2
- FCAR | c.289C>T p.R97C | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.296); catalogued as rs372465584, COSV62030495; called by muse, mutect2, varscan2
- GPR20 | c.325C>T p.R109C | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1197461926, COSV66684068; called by muse, mutect2, varscan2
- GRAMD4 | c.30C>G p.F10L | Missense Mutation (SNP) | VAF 49/270 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as COSV63030895; called by muse, mutect2, varscan2
- HCRTR2 | c.1297C>A p.P433T | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.005); catalogued as COSV63796610; called by muse, mutect2
- KIAA1210 | c.98G>A p.R33Q | Missense Mutation (SNP) | VAF 26/36 reads (72%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0); catalogued as rs747393355, COSV68177862; called by muse, mutect2, varscan2
- MDFIC | c.474G>C p.K158N | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.439); catalogued as rs528031031, COSV57564737; called by muse, mutect2, varscan2
- OMG | c.1301T>C p.V434A | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV55988247; called by muse, mutect2, varscan2
- PITRM1 | c.2225G>C p.G742A | Missense Mutation (SNP) | VAF 12/113 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56533455; called by muse, mutect2, varscan2
- PLA2G7 | c.637G>T p.E213* | Nonsense Mutation (SNP) | VAF 24/78 reads (31%) | catalogued as rs1268429061, COSV51258796; called by muse, mutect2, varscan2
- PLPP3 | c.191G>A p.R64Q | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs749718381, COSV64839715; called by muse, mutect2, varscan2
- PNKP | c.1042C>T p.R348C | Missense Mutation (SNP) | VAF 6/9 reads (67%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs530663093, COSV55587470; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- POF1B | c.242C>T p.T81I | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.015); catalogued as COSV53135702; called by muse, mutect2
- RFX6 | c.1822G>T p.G608* | Nonsense Mutation (SNP) | VAF 7/34 reads (21%) | catalogued as COSV60586261; called by muse, mutect2
- SCUBE1 | c.2806A>T p.I936F | Missense Mutation (SNP) | VAF 12/216 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV62613399; called by muse, mutect2
- SULT4A1 | c.841G>A p.D281N | Missense Mutation (SNP) | VAF 146/430 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.101); catalogued as COSV50781747; called by muse, mutect2, varscan2
- SYN2 | c.1311C>G p.S437R | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.957); catalogued as COSV101413856, COSV70285752, COSV70285999; called by muse, mutect2
- SYNE1 | c.17347-2A>G p.X5783_splice (on ENST00000367255 / NM_182961.4; = p.X5712_splice on NM_033071.3) | Splice Site (SNP) | VAF 25/59 reads (42%) | catalogued as COSV55013705; called by muse, mutect2, varscan2
- TMEM132D | c.1072G>A p.A358T | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.59); PolyPhen benign (0.046); catalogued as rs758754781, COSV70600232; called by muse, mutect2, varscan2
- TNN | c.2888A>C p.K963T | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.868); catalogued as COSV53428718; called by muse, mutect2, varscan2
- UTY | c.1274T>A p.L425* | Nonsense Mutation (SNP) | VAF 8/10 reads (80%) | catalogued as COSV58870342; called by muse, mutect2, varscan2
- ZFP14 | c.565C>T p.Q189* | Nonsense Mutation (SNP) | VAF 12/106 reads (11%) | catalogued as COSV54202943, COSV54203559; called by muse, mutect2, varscan2
- ZNF605 | c.328A>T p.I110F | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.8); PolyPhen possibly damaging (0.636); catalogued as rs1458743622; called by muse, mutect2, varscan2
- RBP3 | c.2365T>A p.Y789N | Missense Mutation (SNP) | VAF 13/17 reads (76%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- CCR4 | c.12G>A p.T4= | Silent (SNP) | VAF 6/27 reads (22%) | catalogued as rs763338260, COSV58382709, COSV58384303; called by muse, mutect2, varscan2
- COL6A3 | c.8583C>T p.N2861= | Silent (SNP) | VAF 40/70 reads (57%) | catalogued as rs375994186; called by muse, mutect2, varscan2
- CRACD | c.2145C>T p.V715= | Silent (SNP) | VAF 11/98 reads (11%) | catalogued as COSV51723871; called by muse, mutect2, varscan2
- EWSR1 | c.1042C>T p.L348= | Silent (SNP) | VAF 29/68 reads (43%) | catalogued as rs1248585912, COSV58424917; called by muse, mutect2, varscan2
- GANC | c.2149C>T p.L717= | Silent (SNP) | VAF 18/47 reads (38%) | catalogued as COSV58809630; called by muse, mutect2, varscan2
- GRM3 | c.1137C>T p.I379= | Silent (SNP) | VAF 30/37 reads (81%) | catalogued as rs759058026, COSV64472598, COSV64479666; called by muse, mutect2, varscan2
- LCK | c.168G>T p.P56= | Silent (SNP) | VAF 11/28 reads (39%) | catalogued as COSV60741043; called by muse, mutect2, varscan2
- MICALL1 | c.2169G>A p.V723= | Silent (SNP) | VAF 31/109 reads (28%) | catalogued as rs778562267, COSV53241378; called by muse, mutect2, varscan2
- MICALL1 | c.2247G>A p.Q749= | Silent (SNP) | VAF 58/156 reads (37%) | catalogued as COSV53241390; called by muse, varscan2
- OR4C13 | c.864G>A p.R288= | Silent (SNP) | VAF 24/80 reads (30%) | catalogued as COSV73648801; called by muse, mutect2, varscan2
- PRAMEF19 | c.91C>T p.L31= | Silent (SNP) | VAF 28/77 reads (36%) | called by muse, varscan2
- SLC7A14 | c.666G>A p.L222= | Silent (SNP) | VAF 3/48 reads (6%) | catalogued as COSV51584150; called by muse, mutect2
- SYNGR1 | c.180C>T p.I60= | Silent (SNP) | VAF 88/223 reads (39%) | catalogued as COSV53368608; called by muse, mutect2, varscan2
